Somatic mutation profile of tumor specimen TCGA-86-8054-01A (aliquot TCGA-86-8054-01A-11D-2238-08) from TCGA case TCGA-86-8054, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.8 years (22,584 days).
Specimen TCGA-86-8054-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1629ec0-3620-49d1-af78-771391afa0d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8054-10A (Blood Derived Normal), aliquot TCGA-86-8054-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8554e9fc-5778-4a05-b034-541a5fc5b581

The open-access MAF lists 233 somatic variants for this specimen: 180 protein-altering or splice-affecting, 48 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 48, Nonsense Mutation 13, Frame Shift Del 7, Splice Site 4, RNA 2, 3'UTR 2, Frame Shift Ins 2, Intron 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESRP1 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1554577402, COSV64411974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.3305C>G p.S1102C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59391201; called by muse, mutect2, varscan2
- ABCA10 | c.3150T>G p.F1050L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV52228295; called by muse, mutect2, varscan2
- ABCC11 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV62325273; called by muse, mutect2, varscan2
- ABCC11 | c.396G>T p.R132S | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs199947088, COSV62325279; called by muse, mutect2, varscan2
- ABCE1 | c.1241A>G p.Q414R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56848604; called by muse, mutect2, varscan2
- ABHD3 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV56677984; called by muse, mutect2, varscan2
- ACAN | c.5922G>A p.M1974I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs1443985437, COSV61367364; called by muse, mutect2, varscan2
- ADAMTS16 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57003282; called by muse, mutect2
- AGMO | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV61121554; called by muse, mutect2, varscan2
- AKT2 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60909949; called by muse, mutect2, varscan2
- ANK1 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 291/413 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV55892199; called by muse, mutect2, varscan2
- ATG16L1 | c.377T>A p.M126K | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT tolerated (0.89); PolyPhen benign (0.03); catalogued as COSV61467441; called by muse, mutect2, varscan2
- ATM | c.1280T>A p.L427* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV53766651; called by muse, mutect2, varscan2
- ATM | c.8144T>G p.L2715R | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53766663; called by muse, mutect2, varscan2
- ATP1B4 | c.504C>A p.N168K (on ENST00000218008 / NM_001142447.3; = p.N164K on NM_012069.5) | Missense Mutation (SNP) | VAF 58/73 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54314410, COSV99486465; called by muse, mutect2, varscan2
- BBS5 | c.503G>T p.W168L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV54753978; called by muse, mutect2, varscan2
- BNC2 | c.808G>C p.A270P | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV66154733; called by muse, mutect2, varscan2
- C2orf78 | c.2228C>A p.S743* | Nonsense Mutation (SNP) | VAF 178/468 reads (38%) | catalogued as rs982874169, COSV68518955; called by muse, mutect2, varscan2
- CACNA1B | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53124706, COSV53143006; called by muse, mutect2, varscan2
- CAPZA1 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54146816; called by muse, varscan2
- CARD11 | c.2960C>T p.T987M | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as rs376039195; called by muse, mutect2, varscan2
- CDH16 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV55338944; called by muse, mutect2, varscan2
- CFAP47 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 29/43 reads (67%) | catalogued as COSV52890123; called by muse, mutect2, varscan2
- CFAP54 | c.6640G>C p.A2214P | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61574477; called by muse, mutect2, varscan2
- CHD8 | c.1790A>T p.E597V (on ENST00000646647 / NM_001170629.2; = p.E318V on NM_020920.4) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV67872263; called by muse, mutect2, varscan2
- CNTNAP2 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62239378; called by muse, mutect2, varscan2
- COL14A1 | c.2248A>T p.S750C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52864829; called by muse, mutect2, varscan2
- COL27A1 | c.3494G>T p.G1165V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100621119; called by muse, mutect2, varscan2
- COL3A1 | c.1186G>T p.G396C | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58594833; called by muse, mutect2, varscan2
- COL4A1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011316; called by muse, mutect2, varscan2
- COL4A1 | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011317; called by muse, mutect2, varscan2
- COX10 | c.918C>A p.S306R | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV55407931; called by muse, mutect2
- CSMD1 | c.1344C>G p.D448E (on ENST00000520002; = p.D447E on NM_033225.6) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.97); catalogued as COSV68245605; called by muse, mutect2, varscan2
- CWH43 | c.811T>G p.S271A | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV56942790; called by muse, varscan2
- CYP4B1 | c.1086A>C p.K362N | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV54725417; called by muse, mutect2, varscan2
- DCC | c.4334C>A p.S1445* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV71439338; called by muse, mutect2, varscan2
- DDX54 | c.2322A>T p.K774N | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58375584; called by muse, mutect2, varscan2
- DLX5 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56032036, COSV56033947; called by muse, mutect2, varscan2
- DMRTB1 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65113784; called by muse, mutect2, varscan2
- DNAAF5 | c.1965G>T p.K655N | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52420230; called by muse, mutect2, varscan2
- DNAH1 | c.1203C>A p.D401E | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV101325752, COSV70234403; called by muse, mutect2, varscan2
- DNAH9 | c.1070G>T p.R357M | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52370172; called by muse, mutect2, varscan2
- DZIP1L | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 24/36 reads (67%) | catalogued as COSV59522896; called by muse, mutect2, varscan2
- ERGIC1 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.038); catalogued as COSV67129096; called by muse, mutect2, varscan2
- EXD1 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59256155; called by muse, mutect2, varscan2
- EXTL1 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.796); catalogued as COSV65338256; called by muse, mutect2, varscan2
- FAM155B | c.1106A>C p.K369T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52937475; called by mutect2, varscan2
- FAM71A | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 99/155 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV54235101, COSV54236851; called by muse, mutect2, varscan2
- FANK1 | c.59T>A p.V20E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64157024; called by muse, mutect2, varscan2
- FASN | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs770233064, COSV60759717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.11163G>T p.K3721N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53159552; called by muse, mutect2, varscan2
- FBXW5 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV56402338, COSV56403861; called by muse, mutect2, varscan2
- FGF10 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV52938435; called by muse, mutect2
- GABRG3 | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV61518485, COSV61529723; called by muse, mutect2, varscan2
- GDAP1 | c.40T>A p.L14M | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.201); catalogued as COSV55186889; called by muse, mutect2, varscan2
- GOT1 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 117/241 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100981782, COSV65147787; called by muse, mutect2, varscan2
- GPR156 | c.600+1G>T p.X200_splice | Splice Site (SNP) | VAF 63/86 reads (73%) | catalogued as COSV59941993; called by muse, mutect2, varscan2
- GRM5 | c.2230C>G p.L744V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs1254186768, COSV59622642; called by muse, mutect2, varscan2
- HELLS | c.2516A>T p.*839Lext*6 | Nonstop Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV53300479; called by muse, mutect2, varscan2
- HMCN1 | c.8231C>A p.T2744N | Missense Mutation (SNP) | VAF 72/109 reads (66%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54930882; called by muse, mutect2, varscan2
- HOXD12 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV66832873, COSV66832991; called by muse, mutect2, varscan2
- INCENP | c.1481C>G p.T494S | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.51); catalogued as COSV53919806; called by muse, mutect2
- INSYN2A | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV54741556; called by muse, mutect2, varscan2
- ITGA8 | c.1826A>T p.D609V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV65228325; called by muse, mutect2, varscan2
- ITIH6 | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778755362, COSV54493200; called by muse, mutect2, varscan2
- ITPKA | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53028966; called by muse, mutect2, varscan2
- ITPR1 | c.2103G>T p.W701C (on ENST00000354582; = p.W686C on NM_002222.7) | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56998823; called by muse, mutect2, varscan2
- KLHL1 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1202021386, COSV64771128, COSV64780056; called by muse, mutect2, varscan2
- KPNA2 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV57858663; called by muse, mutect2, varscan2
- KRTAP9-3 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0.01); catalogued as rs749399739, COSV101370175; called by muse, mutect2, varscan2
- LGR4 | c.2530G>C p.D844H | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156607, COSV58726881; called by muse, mutect2, varscan2
- LUM | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV57128957; called by muse, mutect2, varscan2
- MBOAT1 | c.891C>G p.Y297* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV61127265; called by muse, mutect2, varscan2
- MICAL3 | c.4117del p.Q1373Rfs*65 | Frame Shift Del (DEL) | VAF 104/313 reads (33%) | catalogued as COSV71588086; called by pindel, varscan2
- MNX1 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV53317833; called by muse, mutect2, varscan2
- MPP2 | c.662C>T p.P221L (on ENST00000461854 / NM_001278372.2; = p.P197L on NM_005374.5) | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52239168; called by muse, mutect2, varscan2
- MRGPRF | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1346735937, COSV57996367; called by muse, mutect2
- MUC16 | c.2263G>T p.G755W | Missense Mutation (SNP) | VAF 96/126 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV67485740; called by muse, mutect2, varscan2
- MUC17 | c.4277C>A p.P1426H | Missense Mutation (SNP) | VAF 213/402 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV60299859; called by mutect2, varscan2
- MYH13 | c.5038C>A p.R1680S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52834895, COSV52839329; called by mutect2, varscan2
- MYH7B | c.5436G>A p.M1812I | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as rs1399685905, COSV52683378; called by muse, mutect2, varscan2
- NKX2-1 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); catalogued as COSV61389945; called by muse, mutect2, varscan2
- NLRP10 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs769424048, COSV60782010; called by muse, mutect2, varscan2
- NLRP5 | c.1532C>A p.T511N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs202096610, COSV66766775; called by muse, mutect2, varscan2
- NPAS2 | c.2405A>T p.Q802L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV59561149; called by muse, mutect2, varscan2
- NUP107 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.204); catalogued as COSV57497322; called by muse, mutect2, varscan2
- NUTM2G | c.298T>A p.L100M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100672905; called by muse, mutect2, varscan2
- NWD1 | c.4351G>T p.G1451C | Missense Mutation (SNP) | VAF 79/116 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100343110; called by muse, mutect2, varscan2
- OR14I1 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV61200571; called by muse, mutect2, varscan2
- OR1A1 | c.695del p.G232Afs*31 | Frame Shift Del (DEL) | VAF 31/150 reads (21%) | catalogued as COSV100410758; called by mutect2, pindel, varscan2
- OR2L8 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61727944; called by muse, mutect2, varscan2
- OR2T33 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58817318; called by muse, mutect2, varscan2
- OR4K2 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV53851079; called by muse, mutect2, varscan2
- OTOF | c.3239G>A p.R1080H (on ENST00000272371 / NM_194248.3; = p.R333H on NM_004802.4) | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs397515598, CM094709, COSV55503487; called by muse, mutect2, varscan2
- PAPOLB | c.1843G>T p.V615F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV68202994; called by muse, mutect2, varscan2
- PCDH15 | c.5242C>A p.P1748T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV57374312; called by muse, mutect2, varscan2
- PCDH8 | c.1214C>A p.A405E | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58814622; called by muse, mutect2, varscan2
- PCDHGA6 | c.2253G>T p.Q751H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV54010439; called by muse, mutect2, varscan2
- PCLO | c.14813C>A p.P4938H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100434456; called by muse, mutect2, varscan2
- PDE10A | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 18/22 reads (82%) | catalogued as COSV63103693; called by muse, mutect2, varscan2
- PDYN | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54103151; called by muse, mutect2, varscan2
- PHF20L1 | c.2202G>T p.W734C | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV55196725; called by muse, mutect2, varscan2
- PLEC | c.13693G>C p.V4565L (on ENST00000322810 / NM_201380.4; = p.V4455L on NM_000445.5) | Missense Mutation (SNP) | VAF 136/205 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV59680778; called by muse, mutect2, varscan2
- PLEKHH2 | c.1715G>T p.S572I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1436352697, COSV56759412; called by muse, mutect2
- POLA1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV66889830; called by muse, mutect2, varscan2
- PPM1A | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57788244; called by muse, mutect2, varscan2
- PRKAA2 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.191); catalogued as COSV100982989, COSV64805887; called by muse, mutect2, varscan2
- PRRT3 | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.928); catalogued as COSV55978319; called by muse, mutect2, varscan2
- PSG9 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs199801844, COSV52484148, COSV52485276; called by muse, mutect2, varscan2
- PSPC1 | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV58890120; called by muse, mutect2, varscan2
- PTK2 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV61790605; called by muse, mutect2, varscan2
- PTPRB | c.416T>A p.V139D | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54250384; called by muse, mutect2, varscan2
- PTPRD | c.4921G>T p.V1641F | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV61973815; called by muse, mutect2, varscan2
- RAG1 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100201015, COSV55024436; called by muse, mutect2, varscan2
- RELN | c.6596G>A p.S2199N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV59027793; called by muse, mutect2, varscan2
- RHBDF2 | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV100489509; called by muse, mutect2, varscan2
- RHBDL3 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 142/283 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.232); catalogued as COSV52188429; called by muse, mutect2, varscan2
- RNF6 | c.290-1G>T p.X97_splice | Splice Site (SNP) | VAF 23/32 reads (72%) | catalogued as COSV100644654; called by muse, mutect2, varscan2
- ROR2 | c.1247T>A p.L416Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65222565; called by muse, mutect2, varscan2
- RPGRIP1 | c.1223A>G p.Q408R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.342); catalogued as COSV52855375; called by muse, mutect2, varscan2
- SCN9A | c.5461G>T p.V1821F (on ENST00000303354; = p.V1810F on NM_002977.3) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV57620691; called by muse, mutect2, varscan2
- SCRIB | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57592113; called by muse, mutect2, varscan2
- SECISBP2L | c.3265A>G p.K1089E (on ENST00000559471 / NM_001193489.2; = p.K1044E on NM_014701.4) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV55937014; called by muse, mutect2, varscan2
- SEMA3G | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs369694713; called by muse, mutect2, varscan2
- SEMA5A | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV66802923; called by muse, mutect2, varscan2
- SHANK1 | c.6346C>T p.R2116* | Nonsense Mutation (SNP) | VAF 57/108 reads (53%) | catalogued as COSV53247587; called by muse, mutect2, varscan2
- SLC17A6 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.1); catalogued as COSV54139993; called by muse, mutect2, varscan2
- SLC44A4 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57668775; called by muse, varscan2
- SLC7A9 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50091247; called by muse, mutect2, varscan2
- SLIT2 | c.2057C>G p.T686R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56589973; called by muse, mutect2, varscan2
- SLITRK3 | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV53851265, COSV53852342; called by muse, mutect2, varscan2
- SLX4 | c.4486G>T p.G1496C | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV53567426; called by muse, mutect2, varscan2
- SMTN | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60781630; called by muse, mutect2
- STK10 | c.2869G>T p.A957S | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV51577187, COSV51577795; called by muse, mutect2, varscan2
- STRA8 | c.400A>T p.M134L (on ENST00000275764; = p.M112L on NM_182489.2) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV51962871; called by muse, mutect2, varscan2
- STX17 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV52285346; called by muse, mutect2, varscan2
- TBC1D22A | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV61444245; called by muse, mutect2, varscan2
- TENM3 | c.7592C>T p.A2531V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV69316206; called by muse, mutect2, varscan2
- TG | c.2411T>C p.V804A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV55090279; called by muse, mutect2, varscan2
- TG | c.5120C>A p.P1707H | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV55090290; called by muse, mutect2, varscan2
- THY1 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52455067; called by muse, mutect2, varscan2
- TMEM74B | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67892198; called by muse, mutect2, varscan2
- TPTE | c.1170+1G>T p.X390_splice (on ENST00000618007 / NM_199261.4; = p.X372_splice on NM_199259.4) | Splice Site (SNP) | VAF 10/59 reads (17%) | catalogued as rs770420317; called by muse, mutect2
- TRHDE | c.3053T>G p.L1018* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53860633; called by muse, mutect2, varscan2
- TROAP | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57745557; called by muse, mutect2, varscan2
- TRPC6 | c.805C>A p.H269N | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60259323; called by muse, mutect2, varscan2
- TSHZ3 | c.3149T>C p.F1050S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53679664; called by muse, mutect2, varscan2
- TSHZ3 | c.2846G>A p.W949* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | catalogued as COSV53679682; called by muse, mutect2, varscan2
- UBR4 | c.9941G>A p.G3314D | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64396592; called by muse, mutect2, varscan2
- UGT2B4 | c.1301A>G p.N434S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV59316185, COSV59319751; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1901T>G p.L634R | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV51959253; called by muse, mutect2, varscan2
- UNC13C | c.2558A>T p.Y853F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as rs1271225906, COSV52912263; called by muse, mutect2, varscan2
- USH2A | c.4892C>T p.S1631F | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56418946; called by muse, mutect2, varscan2
- USP20 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59617783; called by muse, mutect2, varscan2
- VPS45 | c.1028G>C p.S343T | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV64888782; called by muse, mutect2, varscan2
- VWA3B | c.2783C>A p.S928Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV68245873; called by muse, mutect2, varscan2
- WASHC5 | c.2452G>T p.V818L | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100572624, COSV59199637; called by muse, mutect2, varscan2
- XPO6 | c.2202G>C p.W734C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58970127; called by muse, mutect2, varscan2
- ZFHX4 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 154/447 reads (34%) | catalogued as COSV51483834; called by muse, mutect2, varscan2
- ZFHX4 | c.5024C>A p.T1675N | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as COSV51488337, COSV51499048; called by muse, mutect2, varscan2
- ZNF143 | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV55181954; called by muse, mutect2, varscan2
- ZNF267 | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV56255571; called by muse, mutect2, varscan2
- ZNF283 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61032378; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53370237; called by muse, mutect2, varscan2
- ZNF761 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs762002172, COSV100483441, COSV61889280; called by muse, mutect2, varscan2
- ZNF770 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 51/208 reads (25%) | catalogued as COSV62544809; called by muse, mutect2, varscan2
- AC024940.1 | n.2144G>C | Splice Region (SNP) | VAF 50/82 reads (61%) | called by muse, mutect2, varscan2
- ASXL2 | c.1707del p.K569Nfs*11 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | called by mutect2, pindel, varscan2
- CDRT1 | c.2160G>T p.R720S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.788); called by muse, mutect2
- CWH43 | c.803_808del p.X268_splice | Splice Site (DEL) | VAF 28/150 reads (19%) | called by pindel, varscan2
- DHRS7C | c.5del p.G2Efs*6 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- H4C2 | c.108del p.R37Afs*14 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.53del p.P18Qfs*9 | Frame Shift Del (DEL) | VAF 126/373 reads (34%) | called by mutect2, pindel, varscan2
- NLRP12 | c.3037dup p.T1013Nfs*29 | Frame Shift Ins (INS) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- PRR16 | c.690_726del p.V231Rfs*20 (on ENST00000407149 / NM_001300783.2; = p.V208Rfs*20 on NM_016644.2) | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel
- STK11 | c.656dup p.Q220Pfs*46 | Frame Shift Ins (INS) | VAF 18/20 reads (90%) | called by mutect2, varscan2
- UMOD | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF84 | c.2054G>T p.C685F | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ABCB5 | c.2085G>A p.G695= (on ENST00000404938 / NM_001163941.2; = p.G250= on NM_178559.6) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1413291631, COSV51715153; called by muse, mutect2
- ANK2 | c.1746C>A p.L582= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV52182020; called by muse, mutect2, varscan2
- ANKS6 | c.1209G>T p.L403= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV62051686; called by muse, mutect2, varscan2
- BPNT2 | c.264C>T p.N88= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as rs1325369677, COSV52908702; called by muse, mutect2, varscan2
- CABIN1 | c.4959C>T p.F1653= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV54087521; called by muse, mutect2, varscan2
- CDH24 | c.2124G>C p.G708= | Silent (SNP) | VAF 68/129 reads (53%) | catalogued as COSV57462850; called by muse, mutect2, varscan2
- CSH1 | c.543A>T p.A181= | Silent (SNP) | VAF 85/237 reads (36%) | catalogued as COSV60242833; called by muse, mutect2, varscan2
- DOCK4 | c.5634G>A p.V1878= | Silent (SNP) | VAF 92/170 reads (54%) | catalogued as COSV70241899; called by muse, mutect2, varscan2
- DSCAML1 | c.2145G>A p.Q715= (on ENST00000321322; = p.Q655= on NM_020693.4) | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV58400337; called by muse, mutect2
- EPHA5 | c.2755C>A p.R919= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV56666563; called by muse, mutect2, varscan2
- FKBP15 | c.42G>T p.S14= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV53038425; called by muse, mutect2, varscan2
- GALNTL6 | c.81C>A p.L27= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV72553109, COSV72553127; called by muse, mutect2, varscan2
- GPR3 | c.508C>T p.L170= | Silent (SNP) | VAF 75/197 reads (38%) | catalogued as COSV64995126; called by muse, mutect2, varscan2
- HAVCR2 | c.426A>G p.R142= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV57154432; called by muse, mutect2
- HINFP | c.69C>T p.S23= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV63432567; called by muse, mutect2, varscan2
- HTR4 | c.543T>A p.S181= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58801919; called by muse, mutect2, varscan2
- ILK | c.600C>T p.N200= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as rs760482273, COSV54991764; ClinVar: likely benign; called by muse, mutect2, varscan2
- LGSN | c.255C>A p.L85= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV101040547, COSV65728257; called by muse, mutect2, varscan2
- LIG1 | c.681G>C p.T227= | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as COSV54395085; called by muse, mutect2, varscan2
- MAP1B | c.5184C>T p.A1728= | Silent (SNP) | VAF 76/138 reads (55%) | catalogued as rs1317776982, COSV57104511; called by muse, mutect2, varscan2
- MRGPRE | c.369G>T p.L123= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1177057406, COSV101100032; called by muse, mutect2, varscan2
- MYO15A | c.8553G>C p.A2851= | Silent (SNP) | VAF 179/256 reads (70%) | catalogued as COSV52763236; called by muse, mutect2, varscan2
- NLRP3 | c.2526T>C p.C842= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV60229755; called by muse, varscan2
- OR4C15 | c.369T>C p.D123= (on ENST00000314644; = p.D69= on NM_001001920.2) | Silent (SNP) | VAF 78/454 reads (17%) | catalogued as COSV58954950; called by muse, mutect2, varscan2
- OR6N2 | c.591G>T p.L197= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as COSV59412696; called by muse, mutect2, varscan2
- OTOF | c.2157G>C p.P719= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV55515220; called by muse, mutect2, varscan2
- PCCB | c.324C>T p.V108= | Silent (SNP) | VAF 40/50 reads (80%) | catalogued as COSV52447653; called by muse, mutect2, varscan2
- PCDH10 | c.2820C>T p.C940= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV52101638; called by muse, mutect2, varscan2
- PTPRZ1 | c.4890G>T p.G1630= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV66443693; called by muse, mutect2, varscan2
- RAB6C | c.441G>A p.G147= | Silent (SNP) | VAF 102/176 reads (58%) | catalogued as COSV69339757; called by muse, mutect2, varscan2
- RGS1 | c.459C>T p.F153= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs367632361; called by muse, mutect2, varscan2
- RHBDF2 | c.1143C>T p.S381= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100489507; called by muse, varscan2
- RHBDF2 | c.996G>A p.V332= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1280968494, COSV57422240, COSV57423525; called by muse, mutect2, varscan2
- RREB1 | c.1704G>T p.G568= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs770296374, COSV58558239, COSV58563310; called by muse, mutect2, varscan2
- SSTR5 | c.819C>T p.A273= | Silent (SNP) | VAF 37/50 reads (74%) | catalogued as rs201298263, COSV53513268; called by muse, mutect2, varscan2
- TBC1D17 | c.549C>G p.L183= | Silent (SNP) | VAF 552/993 reads (56%) | catalogued as COSV55580562; called by muse, mutect2, varscan2
- TELO2 | c.786G>T p.R262= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV51980548; called by muse, mutect2, varscan2
- TEP1 | c.2013G>T p.L671= | Silent (SNP) | VAF 63/246 reads (26%) | catalogued as COSV52998212; called by muse, mutect2, varscan2
- TET1 | c.3477G>T p.R1159= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV65388388; called by muse, mutect2, varscan2
- THBS2 | c.1267C>A p.R423= | Silent (SNP) | VAF 65/85 reads (76%) | catalogued as COSV64681482; called by muse, mutect2, varscan2
- TTBK2 | c.2580C>T p.D860= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs750216427, COSV51173332; called by muse, mutect2, varscan2
- TTN | c.55776C>A p.I18592= (on ENST00000591111; = p.I11168= on NM_003319.4) | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as COSV60273642; called by muse, mutect2
- TXNIP | c.396G>T p.P132= | Silent (SNP) | VAF 176/216 reads (81%) | catalogued as rs782574658, COSV65221198; called by muse, mutect2, varscan2
- UGT2B28 | c.1161G>T p.G387= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV59431453, COSV59433903; called by muse, mutect2, varscan2
- UMOD | c.798C>A p.A266= | Silent (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- UTP25 | c.969C>G p.A323= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV71966118; called by muse, mutect2, varscan2
- VWF | c.8367C>T p.T2789= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV54631043; called by muse, mutect2, varscan2
- WSCD2 | c.1599G>T p.A533= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV54589196; called by muse, mutect2, varscan2
- FAT4 | c.12479+54G>T | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100629186; called by muse, mutect2, varscan2
- ING4 | c.*2T>G | 3'UTR (SNP) | VAF 22/44 reads (50%) | catalogued as COSV99976201; called by muse, mutect2, varscan2
- OR2W5 | n.719G>T | RNA (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- SNORD116-29 | n.38A>C | RNA (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- XIRP2 | c.*733T>C | 3'UTR (SNP) | VAF 6/19 reads (32%) | catalogued as rs759913218, COSV99744921; called by muse, mutect2, varscan2
